Somatic mutation profile of tumor specimen TCGA-2J-AABR-01A (aliquot TCGA-2J-AABR-01A-11D-A40W-08) from TCGA case TCGA-2J-AABR, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 60.6 years (22,131 days).
Specimen TCGA-2J-AABR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5027e0e-4d57-41df-8b70-05162902b343.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABR-10A (Blood Derived Normal), aliquot TCGA-2J-AABR-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af1bc2b4-d608-4fc8-96b5-b2371dc59244

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHSY3 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.527); catalogued as rs959475642; called by muse, mutect2
- FAT2 | c.9428-1G>A p.X3143_splice | Splice Site (SNP) | VAF 22/447 reads (5%) | catalogued as COSV99941325; called by muse, mutect2
- NLRP9 | c.1039G>A p.V347M | Missense Mutation (SNP) | VAF 23/742 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1352594653, COSV100242404; called by muse, mutect2
- NUP155 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 18/564 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.13); catalogued as COSV99192135; called by muse, mutect2
- IRS1 | c.3344A>G p.N1115S | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.095); called by muse, mutect2
- HIVEP3 | c.4359G>A p.E1453= | Silent (SNP) | VAF 20/787 reads (3%) | catalogued as COSV56020141; called by muse, mutect2
